Somatic mutation profile of tumor specimen TCGA-A3-3378-01A (aliquot TCGA-A3-3378-01A-01D-0966-08) from TCGA case TCGA-A3-3378, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 60.5 years (22,090 days).
Specimen TCGA-A3-3378-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4642f7e7-a2c0-4402-97dc-ac91d1b83b30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3378-11A (Solid Tissue Normal), aliquot TCGA-A3-3378-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c359373f-3625-49cc-9a8b-7800b151b39d

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 39, Silent 19, Frame Shift Del 4, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 22/156 reads (14%) | catalogued as COSV63580007; called by muse, mutect2, varscan2
- EPHB4 | c.2953C>G p.P985A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV62268347; called by muse, mutect2, varscan2
- FAM241B | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.124); catalogued as rs778953654, COSV64768752; called by muse, mutect2, varscan2
- FMO5 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs373414071; called by muse, mutect2, varscan2
- IGSF22 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs778827596, COSV60036519; called by muse, mutect2, varscan2
- MTUS2 | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776054880, COSV70917779; called by muse, mutect2, varscan2
- MUC2 | c.3221C>A p.A1074D | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs778455791; called by muse, mutect2, varscan2
- PDC | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as COSV100414777; called by muse, mutect2, varscan2
- PIDD1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as rs527844115; called by muse, mutect2
- POLR2A | c.5533T>C p.S1845P | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); catalogued as rs564268404; called by muse, mutect2, varscan2
- PXDN | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs758869617, COSV53226263; called by muse, mutect2, varscan2
- SLC20A2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1436586846; called by muse, mutect2, varscan2
- SYDE2 | c.1582A>G p.K528E | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1193031525; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2740C>T p.H914Y | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as rs746946950; called by muse, mutect2, varscan2
- ZNF107 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV61329400; called by muse, mutect2, varscan2
- ASTN1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BDH1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP1A1 | c.1083C>G p.D361E | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- DMXL2 | c.7484A>G p.Q2495R | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH2 | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EP300 | c.4376A>T p.K1459M | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM50B | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FMO1 | c.398A>C p.E133A | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GALNT18 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- HIPK2 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- IFIT1 | c.39T>A p.S13R | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNN3 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- LRBA | c.6159G>T p.E2053D | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MAIP1 | c.654G>C p.R218S | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MUC16 | c.40925C>G p.T13642S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MYO1A | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMT2 | c.1398del p.K466Nfs*6 | Frame Shift Del (DEL) | VAF 32/168 reads (19%) | called by mutect2, varscan2
- PADI6 | c.1794_1795del p.I599Pfs*3 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- PBRM1 | c.974del p.N325Ifs*37 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- PDCD6IP | c.1600A>T p.I534F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PDS5B | c.3087G>C p.M1029I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PI4K2B | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PLG | c.1406T>C p.L469P | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPWD1 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRSS12 | c.1082del p.K361Rfs*22 | Frame Shift Del (DEL) | VAF 35/214 reads (16%) | called by mutect2, pindel, varscan2
- RPL12 | c.281_292del p.K94_N97del | In Frame Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- SATB2 | c.1163A>G p.N388S | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SENP1 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- USP32 | c.3070T>G p.F1024V | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB1 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRA3 | c.1365T>A p.S455= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- ANKH | c.627C>T p.C209= | Silent (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- ASTN2 | c.3594A>G p.A1198= (on ENST00000313400 / NM_001365069.1; = p.A1147= on NM_014010.5) | Silent (SNP) | VAF 47/262 reads (18%) | called by muse, mutect2, varscan2
- BMP3 | c.225A>T p.T75= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2
- CCT8 | c.111G>A p.K37= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- DNAJA4 | c.930C>G p.P310= (on ENST00000343789; = p.P339= on NM_018602.3) | Silent (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- ERCC2 | c.1662G>A p.E554= | Silent (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- FRZB | c.120C>A p.I40= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- KRT82 | c.825G>A p.V275= | Silent (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- LELP1 | c.225C>A p.T75= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100907333; called by muse, mutect2, varscan2
- LRRC61 | c.507T>A p.G169= | Silent (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- MAGEB6 | c.363C>G p.G121= | Silent (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- OR2J3 | c.234C>G p.T78= | Silent (SNP) | VAF 71/450 reads (16%) | catalogued as COSV65849512; called by muse, mutect2, varscan2
- PKHD1 | c.10893T>C p.Y3631= | Silent (SNP) | VAF 54/256 reads (21%) | catalogued as rs1290859259, COSV64402908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHCG | c.81G>A p.G27= | Silent (SNP) | VAF 28/219 reads (13%) | called by mutect2, varscan2
- USP24 | c.1410G>A p.L470= | Silent (SNP) | VAF 42/321 reads (13%) | called by muse, mutect2, varscan2
- ZNF182 | c.714A>G p.A238= | Silent (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- ZNF445 | c.2310C>T p.A770= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV101253831; called by muse, mutect2, varscan2
- ZNF543 | c.825G>A p.R275= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs756769639; called by muse, mutect2, varscan2
